TCGA case TCGA-VQ-A922 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8bd783a3-d6c9-4c87-a2a1-09f903b9c7ca

Demographics
Sex at birth: male; Country of residence at enrollment: Brazil; Age at index: 70 years; Vital status: Dead; Days to death: 275 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Tubular adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,700 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 16.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 83 days; Days to treatment end: 85 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Tubular adenocarcinoma), site: Liver. Age at diagnosis: 71.1 years (25,952 days); Days to diagnosis: 252 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 252 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 252 days; Evidence of progression type: Convincing Image Source.
- Follow-up contacts recording only the day: day 262, day 275.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-VQ-A922-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VQ-A922-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A922-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; Cause of death: Stomach Cancer; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 275 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 275 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 252 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A922-01A-11D-A40Z-01): tumor purity 0.35, ploidy 5.76, whole-genome doublings 2.
